Surgical pathology report (de-identified scan), TCGA case TCGA-EM-A22N, project TCGA-THCA (Thyroid Carcinoma), tissue source site University Health Network, specimen TCGA-EM-A22N-01A (Primary Tumor).

[page 1 of 2]
ICD-0-3
carcinoma, papillary, follicular variant
8340/3
Site: thyroid C73.9
lu 4/26/11

Surgical Pathology Consultation Report

Patient Name:		Accession #:
MRN:	Service:	Collected:
DOB:	Visit #:	Received:
Gender: F	Location:	Reported:
HCN:	Facility:	
Ordering MD:		
Copy To:		

Specimen(s) Received

1. Thyroid: RIGHT HEMI THYROID STITCH MARKS RIGHT UPPER POLE - FRESH FOR TISSUE BANKING

Diagnosis

Multifocal papillary carcinoma, dominant oncocyctic follicular variant, 2.0 cm, right; chronic lymphocytic thyroiditis: Thyroid

No pathological diagnosis: Lymph nodes, 2, right perithyroidal
- Right hemithyroidectomy specimen

Synoptic Data

Procedure:	Right hemithyroidectomy
Received:	Fresh
Specimen Integrity:	Intact
Specimen Size:	Right lobe: 5.2 cm 2.5 cm 1.8 cm Isthmus +/- pyramidal lobe: 0.9 cm 0.3 cm 0.2 cm
Specimen Weight:	10.6 g
Tumor Focality:	Multifocal, ipsilateral Multifocal, midline (isthmus)

----- DOMINANT TUMOR -----

Tumor Laterality:	Right lobe
Tumor Size:	Greatest dimension: 2.0cm Additional dimension: 1.4 cm Additional dimension: 1.2 cm

Histologic Type:	Papillary carcinoma, follicular variant Per TSS, follicular variant = 100% Papillary carcinoma, oncocyctic or oxyphilic variant Follicular architecture Classical cytomorphology Oncocyctic or oxyphilic cytomorphology
Histologic Grade:	Not applicable
Margins:	Margins uninvolved by carcinoma

HIVAA Discrepancy		X

[page 2 of 2]
Tumor Capsule:	Totally encapsulated
Tumor Capsular Invasion:	Present, extent minimal
Lymph-Vascular Invasion:	Not identified
Perineural Invasion:	Not identified
Extrathyroidal Extension:	Not identified
----- SECOND TUMOR -----	
Tumor Laterality:	Right lobe
Tumor Size:	Greatest dimension: 1.1 cm Additional dimensions: 0.9 cm
Histologic Type:	Papillary carcinoma, follicular variant Papillary carcinoma, oncocytic or oxyphilic variant Follicular architecture Classical cytomorphology Oncocytic or oxyphilic cytomorphology
Histologic Grade:	Not applicable
Margins:	Margins uninvolved by carcinoma
Tumor Capsule:	Totally encapsulated
Tumor Capsular Invasion:	Present, extent minimal
Lymph-Vascular Invasion:	Not identified
Perineural Invasion:	Not identified
Extrathyroidal Extension:	Not identified
TNM Descriptors:	m (multiple primary tumors)
Primary Tumor (pT):	pT1b: Tumor more than 1 cm but not more than 2 cm in greatest dimension, limited to the thyroid
Regional Lymph Nodes (pN):	pN0: No regional lymph node metastasis Number of regional lymph nodes examined: 2 Number of regional lymph nodes involved: 0
Distant Metastasis (pM):	Not applicable
Additional Pathologic Findings:	Thyroiditis, other: chronic lymphocytic thyroiditis Other: additional multiple papillary microcarcinomas, each 0.1 cm.

*Pathologic Staging is based on AJCC/UICC TNM, 7th Edition

Electronically verified

by:

Gross Description

The specimen labeled with the patient's name and as "Right hemithyroid stitch marks right upper pole", consists of a right hemithyroidectomy, with very little isthmus, specimen that is received oriented with a suture and weighs 10.6 g. The lobe measures 5.2 cm SI x 2.5 cm ML x 1.8 cm AP and the isthmus measures 0.9 SI x 0.3 cm ML x 0.2 cm AP. The external surfaces have fibrous adhesions and are painted with silver nitrate. No parathyroid glands or no lymph nodes are identified grossly. The lobe contains 2 delineated nodules that measure 1.1 cm SI x 0.9 cm ML x 0.9 cm AP and 2.0 cm SI x 1.4 cm ML x 1.2 cm AP. The remainder of the thyroid tissue is unremarkable. Sections of nodule and normal tissue are stored frozen. The remainder of the specimen is submitted as follows:

1A-J lobe, superior to inferior
1K isthmus

Source: NCI Genomic Data Commons file 9bdc2657-62cb-4038-8a54-7a8acddf1327 (TCGA-EM-A22N.B3E28081-82CE-471C-BDC7-78EAB3613AFE.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).